TCGA case TCGA-QK-A8Z8 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: Emory University - Winship Cancer Inst. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ac511727-185b-4ac0-b6c0-dc3a79657be6

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Dead; Days to death: 171 days.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,107 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T3; AJCC clinical N: N1; AJCC clinical M: M1; AJCC clinical stage: Stage IVC; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M1; AJCC pathologic stage: Stage IVC; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel + Fluorouracil; Days to treatment start: 157 days; Days to treatment end: 157 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 171 days; Disease response: With Tumor.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 12; Alcohol days per week: 7.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 80.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-QK-A8Z8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-QK-A8Z8-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-QK-A8Z8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-QK-A8Z8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 7.
- Drug treatment 3: Pharmaceutical therapy drug name: 5-Fluorouracil.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 171 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 171 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 171 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-QK-A8Z8-01A-11D-A390-01): tumor purity 0.7, ploidy 1.89, whole-genome doublings 0.
